Somatic mutation profile of tumor specimen TCGA-BF-AAP8-01A (aliquot TCGA-BF-AAP8-01A-11D-A401-08) from TCGA case TCGA-BF-AAP8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 58.6 years (21,414 days).
Specimen TCGA-BF-AAP8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4334b80-ba31-484a-a81f-c07077e9ecfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-AAP8-10A (Blood Derived Normal), aliquot TCGA-BF-AAP8-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a875986-a034-462a-ab56-527f384164b3

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 39/89 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CD207 | c.35T>C p.F12S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101338601; called by muse, mutect2
- PCDHA2 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV65371830; called by muse, mutect2
- SMARCA4 | c.2523A>T p.R841S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100759239; called by muse, mutect2, varscan2
- SPIDR | c.1429T>C p.W477R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.387); catalogued as COSV99856239; called by muse, mutect2
- USP19 | c.1413G>A p.M471I | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100026567; called by muse, mutect2, varscan2
- BAP1 | c.2054_2056+11del p.X685_splice | Splice Site (DEL) | VAF 16/36 reads (44%) | called by mutect2, pindel
- GPR22 | c.1034dup p.L345Ffs*27 | Frame Shift Ins (INS) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- ADGRF4 | c.1176C>T p.S392= | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as rs1375163365, COSV99349107; called by muse, mutect2, varscan2
- PAMR1 | c.1338C>T p.C446= (on ENST00000619888 / NM_001001991.3; = p.C463= on NM_015430.4) | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs150412568; called by muse, mutect2, varscan2
